Gene-level copy-number profile of tumor specimen ALCH-AFFK-TTP1-A from ALCHEMIST case ALCH-AFFK, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 70.9 years (25,885 days).
Specimen ALCH-AFFK-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 82cc2f60-9203-4930-aad6-4af560f0c1b2.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AFFK-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/e30fa5d7-1bf9-4c63-ba3b-774a922d0a51

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 86; copy number 1: 20,159; copy number 2: 30,460; copy number 3: 7,242; copy number 4: 947; copy number 5: 10; copy number 31: 1.

Homozygous deletions (total copy number 0; autosomes only): 86 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:4,654,609–4,792,534, 2 genes: AJAP1, Z98886.1.
- chr2:24,825,610–24,826,717, 1 gene (within-gene range 0–1): AC012073.1.
- chr3:32,685,145–32,786,116, 4 genes: CNOT10, CNOT10-AS1, SUGT1P2, RPL23AP43.
- chr7:45,816,216–45,843,740, 4 genes: CICP20, AC096582.1, AC096582.2, RNU6-326P.
- chr8:12,172,761–12,194,133, 3 genes (within-gene range 0–2): FAM90A2P, ALG1L11P, FAM86B1.
- chr9:6,704,270–6,727,438, 2 genes (within-gene range 0–1): LINC02851, AL354707.1.
- chr9:6,734,598–6,748,981, 2 genes (within-gene range 0–1): PRELID3BP11, SNRPEP2.
- chr9:125,417,305–125,417,586, 1 gene: Metazoa_SRP.
- chr10:68,846,805–68,846,911, 1 gene (within-gene range 0–1): RNU6-697P.
- chr11:17,719,571–17,722,136, 1 gene: MYOD1.
- chr11:44,260,440–44,310,139, 1 gene: ALX4.
- chr11:70,477,277–70,477,592, 1 gene (within-gene range 0–1): AP001271.1.
- chr15:25,199,448–25,238,067, 22 genes (within-gene range 0–1): SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37.
- chr15:25,243,614–25,243,695, 1 gene (within-gene range 0–1): SNORD115-40.
- chr16:88,638,572–88,640,468, 1 gene: IL17C.
- chr18:37,243,040–37,762,131, 6 genes (within-gene range 0–1): CELF4, AC015961.2, AC090386.1, AC090386.2, AC129908.1, AC009899.1.
- chr18:57,054,558–57,072,119, 1 gene: LINC-ROR.
- chr19:6,572,956–7,087,968, 25 genes: Y_RNA, CD70, RPL7P50, TNFSF14, C3, AC008760.2, GPR108, MIR6791, TRIP10, AC008760.1, SH2D3A, VAV1, ADGRE1, AC020895.2, AC020895.1, Metazoa_SRP, ADGRE4P, AC025278.1, AC025278.2, MBD3L2B, MBD3L5, MBD3L4, MBD3L2, MBD3L3, ZNF557.
- chr19:56,189,570–56,217,777, 3 genes: ZSCAN5B, ZSCAN5C, AC011506.1.
- chr22:23,059,415–23,145,021, 4 genes (within-gene range 0–1): RSPH14, GNAZ, Metazoa_SRP, U7.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 11 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:12,290,071–12,296,180, 1 gene, copy number 31: DEFB131D.
- chr18:5,895,745–6,415,237, 2 genes, copy number 5 (within-gene range 2–5): AP001021.3, L3MBTL4.
- chr18:6,256,747–6,590,653, 8 genes, copy number 5: L3MBTL4-AS1, MIR4317, AP005060.1, RNU6-349P, RPL6P27, AP005202.2, LINC01387, AP005202.1.

Autosomal genes at a single copy (total copy number 1): 17,314. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
